Somatic mutation profile of tumor specimen C3L-03961-05 (aliquot CPT0232670006) from CPTAC case C3L-03961, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 48.6 years (17,760 days).
Specimen C3L-03961-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f8942ea-d367-4ca6-99a0-959daae9678f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03961-31 (Blood Derived Normal), aliquot CPT0232790002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97873138-c7fe-464f-b87f-45d1c21d69b8

The open-access MAF lists 108 somatic variants for this specimen: 72 protein-altering or splice-affecting, 29 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 29, Nonsense Mutation 8, Intron 5, Splice Site 3, Frame Shift Del 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.15088C>T p.R5030C | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1555185875, CM138453, COSV56417619; ClinVar: uncertain significance / pathogenic; called by muse, mutect2
- ABCA3 | c.2393T>A p.L798H | Missense Mutation (SNP) | VAF 32/738 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM140155; called by muse, mutect2
- ARHGAP31 | c.1025G>T p.R342L | Missense Mutation (SNP) | VAF 8/244 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51795926, COSV51798037; called by muse, mutect2
- BRINP2 | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 15/224 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV100838529, COSV64175535; called by muse, mutect2
- CDKN2A | c.357G>T p.E119D | Missense Mutation (SNP) | VAF 36/684 reads (5%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.868); catalogued as COSV100445869; called by muse, mutect2
- COL1A2 | c.917C>T p.T306I | Missense Mutation (SNP) | VAF 16/535 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1562900943; ClinVar: uncertain significance; called by muse, mutect2
- COL6A5 | c.346G>T p.E116* | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | catalogued as COSV55195642; called by muse, mutect2, varscan2
- DCAF12L2 | c.217G>C p.G73R | Missense Mutation (SNP) | VAF 9/244 reads (4%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV63581851, COSV63584283; called by muse, mutect2
- GLIS3 | c.1332C>G p.C444W | Missense Mutation (SNP) | VAF 16/352 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1430943510; called by muse, mutect2
- IGHV3-66 | c.231C>G p.Y77* | Nonsense Mutation (SNP) | VAF 20/458 reads (4%) | catalogued as rs1555572942; called by muse, mutect2
- LYST | c.1421A>G p.N474S | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs531780017; called by muse, mutect2, varscan2
- NLRP8 | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.201); catalogued as rs765907009, COSV99404735; called by muse, mutect2
- PCDHA5 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 22/486 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.226); catalogued as rs782648661, COSV100972241; called by muse, mutect2
- PCLO | c.13909C>T p.P4637S | Missense Mutation (SNP) | VAF 17/327 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61676148; called by muse, mutect2
- PEX5L | c.1315G>A p.G439S | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as rs1056608865; called by muse, mutect2
- PIEZO2 | c.1463C>G p.A488G | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.694); catalogued as COSV100124358; called by muse, mutect2
- PPM1E | c.830G>C p.G277A | Missense Mutation (SNP) | VAF 10/272 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100375833; called by muse, mutect2
- PUS1 | c.1115A>T p.H372L | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV100435148; called by muse, mutect2
- SCN7A | c.3098G>A p.R1033Q | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1355692072, COSV69272739; called by muse, mutect2
- SKIDA1 | c.2026G>T p.D676Y | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.32); catalogued as COSV71611160; called by muse, mutect2
- SLITRK3 | c.2231C>A p.P744H | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99580502; called by muse, mutect2, varscan2
- SPANXN3 | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 9/206 reads (4%) | catalogued as COSV65140682; called by muse, mutect2
- ST8SIA3 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 10/258 reads (4%) | PolyPhen possibly damaging (0.76); catalogued as COSV100129611; called by muse, mutect2
- SYNE1 | c.12266A>T p.Y4089F (on ENST00000367255 / NM_182961.4; = p.Y4018F on NM_033071.3) | Missense Mutation (SNP) | VAF 15/281 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1294787806; called by muse, mutect2
- VPS13A | c.4517A>G p.Y1506C | Missense Mutation (SNP) | VAF 19/313 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749572299; called by muse, mutect2
- ZIK1 | c.1432C>T p.L478F | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV56736755; called by muse, mutect2
- ADGRA1 | c.895G>T p.D299Y | Missense Mutation (SNP) | VAF 24/354 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); called by muse, mutect2
- AHNAK2 | c.15775G>A p.A5259T | Missense Mutation (SNP) | VAF 11/240 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.056); called by muse, mutect2
- ANO9 | c.1769G>A p.R590H | Missense Mutation (SNP) | VAF 18/388 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- AP5B1 | c.2459T>C p.V820A | Missense Mutation (SNP) | VAF 17/242 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); called by muse, mutect2
- ATP8A2 | c.842G>A p.W281* | Nonsense Mutation (SNP) | VAF 9/139 reads (6%) | called by muse, mutect2
- BCHE | c.1009C>T p.L337F | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCDC102B | c.1434+1G>C p.X478_splice | Splice Site (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- CNTN3 | c.2677A>T p.T893S | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- COL3A1 | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 7/181 reads (4%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); called by muse, mutect2
- DEGS1 | c.82+1del | Frame Shift Del (DEL) | VAF 20/149 reads (13%) | called by mutect2, pindel, varscan2
- DLGAP2 | c.2320A>G p.T774A | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); called by muse, mutect2
- DSCAM | c.4648G>T p.V1550L | Missense Mutation (SNP) | VAF 22/215 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DUOX2 | c.2525G>T p.R842L | Missense Mutation (SNP) | VAF 26/613 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); called by muse, mutect2
- EGFL6 | c.68C>A p.A23E | Missense Mutation (SNP) | VAF 13/268 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.141); called by muse, mutect2
- FASTKD1 | c.385G>T p.G129C | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2
- FOXD4L4 | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 35/1101 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2
- GATM | c.1075T>A p.S359T | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); called by muse, mutect2
- GPR42 | c.569T>A p.V190E | Missense Mutation (SNP) | VAF 18/420 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- GRIN3A | c.2110A>T p.T704S | Missense Mutation (SNP) | VAF 9/276 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- IGSF21 | c.577G>C p.V193L | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.222); called by muse, mutect2
- KIT | c.574G>T p.G192C | Missense Mutation (SNP) | VAF 17/310 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- KLHL4 | c.403A>T p.I135L | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, varscan2
- KRTAP5-11 | c.244T>C p.C82R | Missense Mutation (SNP) | VAF 18/535 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); called by muse, mutect2
- LRFN5 | c.1467A>G p.I489M | Missense Mutation (SNP) | VAF 10/217 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.254); called by muse, mutect2
- NT5DC4 | c.1248+1G>C p.X416_splice | Splice Site (SNP) | VAF 10/216 reads (5%) | called by muse, mutect2
- OCSTAMP | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 7/146 reads (5%) | called by muse, mutect2
- OR14C36 | c.415T>A p.C139S | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OTOG | c.8683C>A p.Q2895K | Missense Mutation (SNP) | VAF 32/624 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.2); called by muse, mutect2
- POTEF | c.1117A>T p.S373C | Missense Mutation (SNP) | VAF 11/296 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.612); called by muse, mutect2
- PRDM9 | c.682A>T p.S228C | Missense Mutation (SNP) | VAF 22/476 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.011); called by muse, mutect2
- RAB3GAP2 | c.790A>G p.I264V | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SETBP1 | c.4541A>T p.H1514L | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.286); called by muse, mutect2
- SNTA1 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 13/278 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- ST8SIA3 | c.587C>A p.A196D | Missense Mutation (SNP) | VAF 7/193 reads (4%) | PolyPhen benign (0.113); called by muse, mutect2
- STK39 | c.1002C>A p.C334* | Nonsense Mutation (SNP) | VAF 14/202 reads (7%) | called by muse, mutect2
- SYT10 | c.718C>A p.Q240K | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2
- TERT | c.2818C>A p.L940M | Missense Mutation (SNP) | VAF 20/341 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- TMEM132C | c.206A>T p.Q69L | Missense Mutation (SNP) | VAF 8/246 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2
- TRIM6 | c.831G>C p.M277I | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- TRPS1 | c.1007A>T p.K336I (on ENST00000220888 / NM_001330599.2; = p.K349I on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/151 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TTN | c.4979T>A p.L1660* (on ENST00000591111; = p.L1614* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- UBR1 | c.3509+2T>G p.X1170_splice | Splice Site (SNP) | VAF 17/438 reads (4%) | called by muse, mutect2
- ZCCHC14 | c.884C>T p.T295I (on ENST00000268616; = p.T432I on NM_015144.3) | Missense Mutation (SNP) | VAF 16/326 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); called by muse, mutect2
- ZNF180 | c.1870C>T p.Q624* | Nonsense Mutation (SNP) | VAF 7/114 reads (6%) | called by muse, mutect2
- ZNF420 | c.1208G>T p.G403V | Missense Mutation (SNP) | VAF 13/191 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.321); called by muse, mutect2
- ZNF804B | c.3890G>C p.G1297A | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.018); called by muse, mutect2
- AKAP13 | c.2073A>G p.E691= | Silent (SNP) | VAF 7/150 reads (5%) | called by muse, mutect2
- ANKRD26 | c.327T>C p.C109= | Silent (SNP) | VAF 42/410 reads (10%) | catalogued as rs1183431335; called by muse, mutect2, varscan2
- APOB | c.5445G>A p.R1815= | Silent (SNP) | VAF 8/162 reads (5%) | called by muse, mutect2
- ARHGEF37 | c.385T>C p.L129= | Silent (SNP) | VAF 11/334 reads (3%) | called by muse, mutect2
- CBY2 | c.639G>T p.R213= | Silent (SNP) | VAF 9/157 reads (6%) | catalogued as COSV60117756; called by muse, mutect2
- CCDC141 | c.2928A>G p.P976= | Silent (SNP) | VAF 10/205 reads (5%) | catalogued as rs1236330130; called by muse, mutect2
- CIC | c.2223C>A p.A741= | Silent (SNP) | VAF 21/582 reads (4%) | called by muse, mutect2
- CIT | c.3228G>C p.A1076= | Silent (SNP) | VAF 10/160 reads (6%) | called by muse, mutect2
- DNAH17 | c.3918T>C p.V1306= | Silent (SNP) | VAF 10/256 reads (4%) | called by muse, mutect2
- DNAH5 | c.5220C>G p.A1740= | Silent (SNP) | VAF 20/327 reads (6%) | called by muse, mutect2
- FCHO1 | c.2535C>A p.P845= | Silent (SNP) | VAF 16/264 reads (6%) | called by muse, mutect2
- GABRG2 | c.1458G>T p.R486= (on ENST00000361925 / NM_001375343.1; = p.R446= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/274 reads (4%) | catalogued as COSV100729593, COSV100729651; called by muse, mutect2
- GALNT17 | c.1461C>T p.H487= | Silent (SNP) | VAF 8/141 reads (6%) | called by muse, mutect2
- GGA2 | c.1029C>T p.C343= | Silent (SNP) | VAF 11/204 reads (5%) | catalogued as rs1439155557; called by muse, mutect2
- GLIS3 | c.63C>T p.N21= | Silent (SNP) | VAF 18/503 reads (4%) | catalogued as COSV60930571; called by muse, mutect2
- H1-8 | c.609G>A p.A203= | Silent (SNP) | VAF 18/414 reads (4%) | catalogued as rs192410545, COSV60974646; called by muse, mutect2
- HMCN2 | c.2335C>T p.L779= | Silent (SNP) | VAF 8/143 reads (6%) | called by muse, mutect2
- KCNK18 | c.81C>G p.L27= | Silent (SNP) | VAF 26/630 reads (4%) | called by muse, mutect2
- KIR3DL2 | c.564C>A p.V188= | Silent (SNP) | VAF 30/711 reads (4%) | called by muse, mutect2
- NID1 | c.339G>T p.T113= | Silent (SNP) | VAF 27/279 reads (10%) | catalogued as COSV51626519; called by muse, mutect2
- OR2M3 | c.210C>T p.D70= | Silent (SNP) | VAF 17/174 reads (10%) | catalogued as rs768597426; called by muse, mutect2, varscan2
- PCDHA1 | c.1896C>T p.S632= | Silent (SNP) | VAF 16/392 reads (4%) | called by muse, mutect2
- PLXNB2 | c.1005G>T p.R335= | Silent (SNP) | VAF 10/262 reads (4%) | called by muse, mutect2
- PSD2 | c.667C>A p.R223= | Silent (SNP) | VAF 21/231 reads (9%) | catalogued as rs374016750; called by muse, mutect2
- SDF2L1 | c.225G>A p.S75= | Silent (SNP) | VAF 26/455 reads (6%) | catalogued as rs933313566; called by muse, mutect2
- SHISA6 | c.549G>T p.G183= | Silent (SNP) | VAF 36/690 reads (5%) | called by muse, mutect2
- TBXT | c.1218G>A p.A406= | Silent (SNP) | VAF 18/436 reads (4%) | catalogued as rs1157647187, COSV51619756; called by muse, mutect2
- ZHX1 | c.1080G>T p.V360= | Silent (SNP) | VAF 6/116 reads (5%) | called by muse, mutect2
- ZNF469 | c.10543C>T p.L3515= (on ENST00000437464; = p.L3543= on NM_001367624.2) | Silent (SNP) | VAF 10/224 reads (4%) | called by muse, mutect2
- AL162726.3 | n.255+83317T>G | Intron (SNP) | VAF 20/588 reads (3%) | called by muse, mutect2
- APTX | c.875-28G>T | Intron (SNP) | VAF 16/448 reads (4%) | called by muse, mutect2
- C11orf40 | n.223C>A | RNA (SNP) | VAF 15/213 reads (7%) | called by muse, mutect2
- C2CD6 | c.1581+2066A>T | Intron (SNP) | VAF 9/62 reads (15%) | catalogued as rs752092376; called by muse, mutect2, varscan2
- RGPD4 | c.-48G>C | 5'UTR (SNP) | VAF 15/412 reads (4%) | called by muse, mutect2
- SNX6 | c.42+22G>C | Intron (SNP) | VAF 8/133 reads (6%) | called by muse, mutect2
- ZIC4 | c.-15-1163C>A | Intron (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
